Somatic mutation profile of tumor specimen C3N-00322-03 (aliquot CPT0010430006) from CPTAC case C3N-00322, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G2; Age at diagnosis: 70.5 years (25,752 days).
Specimen C3N-00322-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 498e30a7-ce7e-4ad1-895e-11cde14a355e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00322-71 (Blood Derived Normal), aliquot CPT0077050001; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/74b1105e-10bc-4162-8ca7-543a78847e48

The open-access MAF lists 104 somatic variants for this specimen: 68 protein-altering or splice-affecting, 29 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 53, Silent 29, Frame Shift Ins 6, Nonsense Mutation 4, Intron 3, 3'UTR 2, Frame Shift Del 2, In Frame Del 2, RNA 1, Splice Site 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DYRK1A | c.452dup p.N151Kfs*12 | Frame Shift Ins (INS) | VAF 13/65 reads (20%) | catalogued as rs797044523; ClinVar: pathogenic; called by mutect2, pindel
- FGFR2 | c.755C>G p.S252W | Missense Mutation (SNP) | VAF 24/75 reads (32%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs79184941, CM950458, CM970526, COSV60638319; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3R2 | c.1117G>A p.G373R | Missense Mutation (SNP) | VAF 12/81 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587776934, CM126686, COSV55846573; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PROK2 | c.297dup p.G100Wfs*22 (on ENST00000295619 / NM_001126128.2; = p.G79Wfs*22 on NM_021935.4) | Frame Shift Ins (INS) | VAF 29/232 reads (13%) | catalogued as rs768413190; ClinVar: likely pathogenic; called by mutect2, varscan2
- AMZ1 | c.398C>T p.P133L | Missense Mutation (SNP) | VAF 46/213 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs762909854, COSV56687649; called by muse, mutect2, varscan2
- ANO2 | c.671C>T p.A224V (on ENST00000356134 / NM_001278597.3; = p.A228V on NM_001278596.3) | Missense Mutation (SNP) | VAF 22/169 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.065); catalogued as rs1004961555, COSV100502527, COSV59043398; called by muse, mutect2, varscan2
- ASXL2 | c.3358A>G p.M1120V | Missense Mutation (SNP) | VAF 46/261 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.824); catalogued as rs767987419; called by muse, mutect2, varscan2
- BRINP2 | c.1111C>T p.R371C | Missense Mutation (SNP) | VAF 72/567 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as rs759275578, COSV64178261; called by muse, mutect2, varscan2
- CD276 | c.1246G>A p.E416K (on ENST00000318443 / NM_001024736.2; = p.E198K on NM_025240.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 88/503 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.577); catalogued as rs762905746; called by muse, mutect2, varscan2
- CDC25B | c.251G>A p.R84H (on ENST00000245960 / NM_021873.3; = p.R70H on NM_004358.4) | Missense Mutation (SNP) | VAF 34/199 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.29); catalogued as rs866490685, COSV55654824; called by muse, mutect2, varscan2
- CKM | c.391G>A p.V131I | Missense Mutation (SNP) | VAF 40/257 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.024); catalogued as rs200253404, COSV55532400; called by muse, mutect2, varscan2
- CLVS1 | c.880G>A p.D294N | Missense Mutation (SNP) | VAF 24/125 reads (19%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.483); catalogued as COSV57970325; called by muse, mutect2, varscan2
- COL2A1 | c.3803G>A p.S1268N | Missense Mutation (SNP) | VAF 64/300 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100475849; called by muse, mutect2, varscan2
- CSMD3 | c.2172C>A p.N724K (on ENST00000297405 / NM_001363185.1; = p.N620K on NM_052900.3) | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748765119; called by muse, mutect2, varscan2
- CSPG4 | c.2977G>A p.E993K | Missense Mutation (SNP) | VAF 25/149 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as rs1387915856, COSV57892314; called by muse, mutect2, varscan2
- CTNNA2 | c.1051A>C p.N351H | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.903); catalogued as rs1185995811, COSV63547281; called by mutect2, varscan2
- DCTN1 | c.2974G>A p.E992K | Missense Mutation (SNP) | VAF 85/398 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.113); catalogued as rs768409522; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EPHA3 | c.1340G>A p.R447Q | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as rs925530491, COSV60702619; called by muse, mutect2, varscan2
- FTSJ3 | c.339_341del p.V114del | In Frame Del (DEL) | VAF 32/215 reads (15%) | catalogued as rs761565909; called by pindel, varscan2
- GSTA2 | c.89T>C p.F30S | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs780797754; called by muse, mutect2, varscan2
- GSTZ1 | c.151C>T p.Q51* | Nonsense Mutation (SNP) | VAF 31/213 reads (15%) | catalogued as rs1482764002; called by muse, mutect2, varscan2
- IMPG1 | c.914C>A p.T305K | Missense Mutation (SNP) | VAF 29/126 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.499); catalogued as COSV64055755; called by muse, mutect2, varscan2
- INCENP | c.2189G>A p.R730Q (on ENST00000394818 / NM_001040694.2; = p.R726Q on NM_020238.3) | Missense Mutation (SNP) | VAF 56/286 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as rs753193933, COSV99610584; called by muse, mutect2, varscan2
- IRF8 | c.784C>T p.R262* | Nonsense Mutation (SNP) | VAF 68/325 reads (21%) | catalogued as rs1355753577; called by muse, mutect2, varscan2
- ITGAE | c.2098G>A p.V700I | Missense Mutation (SNP) | VAF 11/143 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as rs967609574, COSV53993808; called by muse, mutect2
- LYVE1 | c.553C>A p.P185T | Missense Mutation (SNP) | VAF 30/186 reads (16%) | SIFT tolerated (0.38); PolyPhen benign (0.154); catalogued as rs749336203, COSV56282712; called by muse, mutect2, varscan2
- MFSD2B | c.1387G>A p.A463T | Missense Mutation (SNP) | VAF 19/215 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.701); catalogued as rs751215494, COSV57853996; called by muse, mutect2
- MUC4 | c.8704C>A p.L2902I | Missense Mutation (SNP) | VAF 97/772 reads (13%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.374); catalogued as rs866505765; called by muse, varscan2
- PCDHA12 | c.1556C>T p.A519V | Missense Mutation (SNP) | VAF 113/788 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.753); catalogued as rs367864661; called by muse, mutect2, varscan2
- POU2F1 | c.2215G>A p.A739T (on ENST00000541643 / NM_001365848.1; = p.A762T on NM_002697.4) | Missense Mutation (SNP) | VAF 24/143 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.141); catalogued as rs774822872, COSV54825379; called by muse, mutect2, varscan2
- PTEN | c.878del p.G293Efs*14 | Frame Shift Del (DEL) | VAF 77/215 reads (36%) | catalogued as COSV64306603; called by mutect2, pindel, varscan2
- RAB3IL1 | c.311G>A p.R104Q | Missense Mutation (SNP) | VAF 31/244 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs536709910, COSV57117239; called by muse, mutect2, varscan2
- SBK2 | c.644G>A p.R215H | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.581); catalogued as rs1239093167; called by muse, mutect2, varscan2
- SERGEF | c.425G>A p.C142Y | Missense Mutation (SNP) | VAF 26/191 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as rs750134618; called by muse, mutect2, varscan2
- SLC5A8 | c.298G>A p.A100T | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.068); catalogued as rs974949950; called by muse, mutect2, varscan2
- SLITRK1 | c.1172G>A p.R391Q | Missense Mutation (SNP) | VAF 70/397 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.138); catalogued as COSV65674545; called by muse, mutect2, varscan2
- STX7 | c.497G>A p.R166H | Missense Mutation (SNP) | VAF 24/163 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs746775126; called by muse, mutect2, varscan2
- SVOP | c.584C>T p.T195M | Missense Mutation (SNP) | VAF 23/189 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs963472116, COSV54466716; called by muse, mutect2, varscan2
- TBXA2R | c.473C>A p.A158E | Missense Mutation (SNP) | VAF 92/329 reads (28%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.737); catalogued as COSV64343867; called by muse, mutect2, varscan2
- TEAD2 | c.1304G>A p.R435H | Missense Mutation (SNP) | VAF 44/233 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1363413403; called by muse, mutect2, varscan2
- TMEM132D | c.1574C>T p.P525L | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV67158700; called by muse, mutect2, varscan2
- TTN | c.96784C>T p.R32262C (on ENST00000591111; = p.R24838C on NM_003319.4) | Missense Mutation (SNP) | VAF 19/79 reads (24%) | PolyPhen probably damaging (0.999); catalogued as rs772574722, COSV60047211; called by muse, mutect2, varscan2
- TUBB8 | c.1196C>T p.T399M | Missense Mutation (SNP) | VAF 14/358 reads (4%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.949); catalogued as rs1456332226, COSV100226069, COSV59116788; called by muse, mutect2
- UMODL1 | c.2635G>A p.A879T (on ENST00000408910 / NM_001004416.2; = p.A1007T on NM_173568.3) | Missense Mutation (SNP) | VAF 44/273 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.763); catalogued as rs374395575, COSV68569581; called by muse, mutect2, varscan2
- ARHGEF19 | c.1294G>T p.E432* | Nonsense Mutation (SNP) | VAF 9/46 reads (20%) | called by muse, mutect2, varscan2
- ATP7A | c.3803T>C p.V1268A | Missense Mutation (SNP) | VAF 10/196 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2
- BCR | c.760dup p.R254Pfs*14 | Frame Shift Ins (INS) | VAF 37/150 reads (25%) | called by mutect2, pindel, varscan2
- CPXM2 | c.779A>G p.N260S | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT tolerated (0.39); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- CYP4F8 | c.404G>A p.G135E | Missense Mutation (SNP) | VAF 20/123 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- F5 | c.5130G>T p.W1710C | Missense Mutation (SNP) | VAF 38/303 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FBXO10 | c.2120_2121del p.E707Afs*18 | Frame Shift Del (DEL) | VAF 24/144 reads (17%) | called by pindel, varscan2
- HOXC12 | c.91G>A p.A31T | Missense Mutation (SNP) | VAF 47/230 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- IFT43 | c.412G>A p.D138N (on ENST00000314067 / NM_001102564.3; = p.D143N on NM_052873.3) | Missense Mutation (SNP) | VAF 76/406 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LRRC14 | c.1145dup p.L383Vfs*40 | Frame Shift Ins (INS) | VAF 42/260 reads (16%) | called by mutect2, pindel, varscan2
- MAP3K5 | c.908_915dup p.I306* | Nonsense Mutation (INS) | VAF 24/110 reads (22%) | called by mutect2, varscan2
- NHSL1 | c.737C>G p.S246C | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- NOTCH1 | c.2832_2834del p.E944del | In Frame Del (DEL) | VAF 86/432 reads (20%) | called by pindel, varscan2
- OPA1 | c.890A>G p.E297G (on ENST00000361510 / NM_130837.3; = p.E242G on NM_015560.3) | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.437); called by muse, mutect2, varscan2
- PALD1 | c.2264C>A p.A755E | Missense Mutation (SNP) | VAF 41/84 reads (49%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- PIK3R1 | c.1984_1985+3dup | Frame Shift Ins (INS) | VAF 16/68 reads (24%) | called by mutect2, varscan2
- PLPPR5 | c.28_32dup p.S11Rfs*10 | Frame Shift Ins (INS) | VAF 45/208 reads (22%) | called by pindel, varscan2
- RGS1 | c.401A>T p.E134V | Missense Mutation (SNP) | VAF 28/201 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.409); called by muse, mutect2, varscan2
- SCAF4 | c.159+1G>T p.X53_splice | Splice Site (SNP) | VAF 7/47 reads (15%) | called by muse, mutect2, varscan2
- SLFN12L | c.1067G>A p.S356N (on ENST00000260908 / NM_001363830.1; = p.S374N on NM_001195790.1) | Missense Mutation (SNP) | VAF 24/170 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2
- SNX17 | c.20A>C p.E7A | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- TFDP3 | c.675A>T p.Q225H | Missense Mutation (SNP) | VAF 13/191 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.398); called by muse, mutect2
- ZCCHC12 | c.17C>T p.A6V | Missense Mutation (SNP) | VAF 10/244 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.548); called by muse, mutect2
- ZNF185 | c.1477G>A p.A493T | Missense Mutation (SNP) | VAF 31/143 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- ACAN | c.6696G>T p.T2232= | Silent (SNP) | VAF 85/474 reads (18%) | catalogued as COSV100717336; called by muse, mutect2, varscan2
- API5 | c.63G>T p.V21= | Silent (SNP) | VAF 31/147 reads (21%) | called by muse, mutect2, varscan2
- CACNA1E | c.4383G>A p.P1461= | Silent (SNP) | VAF 99/265 reads (37%) | catalogued as rs761748918, COSV62387110; called by muse, mutect2, varscan2
- CCDC93 | c.873C>T p.S291= | Silent (SNP) | VAF 36/208 reads (17%) | catalogued as rs759873941; called by muse, mutect2, varscan2
- CGB1 | c.162C>A p.G54= | Silent (SNP) | VAF 55/385 reads (14%) | called by muse, mutect2, varscan2
- CNOT4 | c.1521C>T p.S507= (on ENST00000315544 / NM_001190848.1; = p.S504= on NM_013316.4) | Silent (SNP) | VAF 30/188 reads (16%) | called by muse, mutect2, varscan2
- CYP4B1 | c.1497C>T p.H499= | Silent (SNP) | VAF 35/132 reads (27%) | called by muse, mutect2, varscan2
- DSEL | c.636T>A p.V212= | Silent (SNP) | VAF 34/195 reads (17%) | called by muse, mutect2, varscan2
- GAS8 | c.1128C>T p.A376= | Silent (SNP) | VAF 64/375 reads (17%) | catalogued as rs149280611; ClinVar: likely benign; called by muse, mutect2, varscan2
- GATA3 | c.1032C>T p.Y344= | Silent (SNP) | VAF 123/470 reads (26%) | called by muse, mutect2, varscan2
- GCNT4 | c.816A>G p.R272= | Silent (SNP) | VAF 28/200 reads (14%) | called by muse, mutect2, varscan2
- GDAP1L1 | c.411G>T p.L137= | Silent (SNP) | VAF 30/152 reads (20%) | called by muse, mutect2, varscan2
- IGFN1 | c.1083C>T p.D361= | Silent (SNP) | VAF 22/180 reads (12%) | catalogued as rs367631324; called by muse, mutect2, varscan2
- KCNQ1 | c.1107G>A p.P369= | Silent (SNP) | VAF 59/349 reads (17%) | catalogued as rs746037904; ClinVar: likely benign; called by muse, mutect2, varscan2
- MYO1C | c.1968C>T p.R656= (on ENST00000648651 / NM_001080779.2; = p.R621= on NM_033375.5) | Silent (SNP) | VAF 49/251 reads (20%) | catalogued as rs750688193; called by muse, mutect2, varscan2
- NPAT | c.2400A>G p.V800= | Silent (SNP) | VAF 57/283 reads (20%) | catalogued as rs764476963; called by muse, mutect2, varscan2
- NPC1L1 | c.3795C>T p.F1265= | Silent (SNP) | VAF 69/308 reads (22%) | called by muse, mutect2, varscan2
- OR6B1 | c.198G>A p.L66= | Silent (SNP) | VAF 32/123 reads (26%) | called by muse, mutect2, varscan2
- P2RX1 | c.960C>T p.D320= | Silent (SNP) | VAF 49/300 reads (16%) | catalogued as rs139414872; called by muse, mutect2, varscan2
- PCDHA4 | c.1278C>T p.T426= | Silent (SNP) | VAF 90/400 reads (23%) | catalogued as rs372009115, COSV100793699; called by muse, mutect2, varscan2
- PCDHB2 | c.1560G>A p.S520= | Silent (SNP) | VAF 175/840 reads (21%) | catalogued as rs1398124097, COSV50580746, COSV50608706; called by muse, mutect2, varscan2
- PCDHGA2 | c.2232C>T p.D744= | Silent (SNP) | VAF 96/481 reads (20%) | catalogued as COSV53897900; called by muse, mutect2, varscan2
- PIK3R5 | c.1560G>A p.V520= | Silent (SNP) | VAF 57/329 reads (17%) | catalogued as COSV52653059; called by muse, mutect2, varscan2
- PLPPR5 | c.27C>T p.T9= | Silent (SNP) | VAF 44/192 reads (23%) | called by muse, varscan2
- PRPF8 | c.3553C>T p.L1185= | Silent (SNP) | VAF 81/472 reads (17%) | called by muse, mutect2, varscan2
- RUNX1 | c.1152C>T p.A384= (on ENST00000344691 / NM_001001890.3; = p.A411= on NM_001754.5) | Silent (SNP) | VAF 39/240 reads (16%) | catalogued as rs1310943509, COSV55895972; called by muse, mutect2, varscan2
- TRPV4 | c.1878C>T p.I626= | Silent (SNP) | VAF 78/499 reads (16%) | catalogued as rs758026363, COSV55681695; called by muse, mutect2, varscan2
- TSPYL1 | c.159C>T p.G53= | Silent (SNP) | VAF 39/211 reads (18%) | called by muse, mutect2, varscan2
- ZNF513 | c.1431C>T p.C477= | Silent (SNP) | VAF 89/557 reads (16%) | catalogued as rs755750194; called by muse, mutect2, varscan2
- AL353804.6 | chrX:73827620 C>T | 3'Flank (SNP) | VAF 18/456 reads (4%) | catalogued as rs1216188318; called by muse, mutect2
- CHIT1 | c.*631G>T | 3'UTR (SNP) | VAF 72/527 reads (14%) | called by muse, mutect2, varscan2
- CYP11B1 | c.239+191C>A | Intron (SNP) | VAF 16/165 reads (10%) | called by muse, mutect2, varscan2
- GLTPP1 | n.348G>A | RNA (SNP) | VAF 23/112 reads (21%) | catalogued as rs1233375259; called by muse, mutect2
- YWHAZ | c.294+478C>T | Intron (SNP) | VAF 8/88 reads (9%) | catalogued as rs1357091777; called by muse, mutect2
- ZNF720 | c.361+1458G>T | Intron (SNP) | VAF 13/61 reads (21%) | catalogued as rs1217237006, COSV100335456; called by muse, mutect2, varscan2
- ZNF99 | c.*373G>A | 3'UTR (SNP) | VAF 8/71 reads (11%) | called by muse, mutect2, varscan2
